Somatic mutation profile of tumor specimen TCGA-G3-A25V-01A (aliquot TCGA-G3-A25V-01A-11D-A16V-10) from TCGA case TCGA-G3-A25V, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 68.8 years (25,144 days).
Specimen TCGA-G3-A25V-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3fb68406-64a0-40d4-8aed-cd918804da86.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-G3-A25V-10A (Blood Derived Normal), aliquot TCGA-G3-A25V-10A-01D-A16V-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/05dc3be3-6e16-47b0-8275-91de2b413656

The open-access MAF lists 62 somatic variants for this specimen: 42 protein-altering or splice-affecting, 13 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 30, Silent 13, Frame Shift Del 5, 3'UTR 3, Intron 3, Nonsense Mutation 3, Splice Site 2, In Frame Ins 1, Frame Shift Ins 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.750del p.I251Sfs*94 | Frame Shift Del (DEL) | VAF 69/317 reads (22%) | catalogued as rs1567549203, COSV52876092; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ACTC1 | c.920T>C p.M307T | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.446); catalogued as rs1422171214, COSV51758818; called by muse, mutect2, varscan2
- ADGRL4 | c.2011-1G>A p.X671_splice | Splice Site (SNP) | VAF 39/268 reads (15%) | catalogued as rs1337265043, COSV66061367; called by muse, mutect2, varscan2
- ALOXE3 | c.1426C>T p.L476F | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.176); catalogued as rs1198565136, COSV59075507; called by muse, mutect2, varscan2
- AP1G2 | c.1222G>C p.A408P | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55338059; called by mutect2, varscan2
- ASB12 | c.403A>G p.S135G | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV62856807; called by muse, mutect2, varscan2
- BIRC6 | c.1412G>A p.G471E | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.98); catalogued as COSV70198662; called by mutect2, varscan2
- C9orf152 | c.437G>A p.G146E | Missense Mutation (SNP) | VAF 17/97 reads (18%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as COSV68762842; called by muse, mutect2, varscan2
- CAPS2 | c.1009A>G p.T337A | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.013); catalogued as rs372993486, COSV60825270; called by muse, mutect2, varscan2
- CHST2 | c.1357C>T p.Q453* | Nonsense Mutation (SNP) | VAF 9/62 reads (15%) | catalogued as COSV58885398; called by muse, mutect2, varscan2
- COL11A1 | c.5276C>A p.S1759Y | Missense Mutation (SNP) | VAF 13/97 reads (13%) | SIFT tolerated (1); PolyPhen possibly damaging (0.5); catalogued as COSV62182174; called by muse, mutect2, varscan2
- COL15A1 | c.3680T>C p.F1227S | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.494); catalogued as rs747424432, COSV66644123; called by muse, mutect2, varscan2
- CUX1 | c.161C>T p.A54V (on ENST00000292535 / NM_181552.4; = p.A65V on NM_001913.5) | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as COSV52897999; called by mutect2, varscan2
- DDB2 | c.851C>A p.S284* | Nonsense Mutation (SNP) | VAF 8/52 reads (15%) | catalogued as rs773602928, COSV57038193; called by mutect2, varscan2
- DNAJC24 | c.160G>A p.E54K | Missense Mutation (SNP) | VAF 9/97 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.026); catalogued as COSV71938607; called by muse, mutect2
- DPAGT1 | c.1172G>A p.S391N | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.318); catalogued as COSV53828312; called by muse, mutect2
- DSC2 | c.2570A>G p.Y857C | Missense Mutation (SNP) | VAF 27/121 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51864178; called by muse, mutect2, varscan2
- EEF1A1 | c.1295C>T p.T432I | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.833); catalogued as COSV58549515; called by muse, mutect2, varscan2
- EEF1A1 | c.1294A>T p.T432S | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.042); catalogued as COSV58548569, COSV58549078; called by muse, mutect2, varscan2
- FCGR3B | c.14T>G p.L5R | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV54209831; called by muse, varscan2
- GRIA4 | c.486G>T p.R162S | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.928); catalogued as COSV56894202, COSV56908240; called by mutect2, varscan2
- GRTP1 | c.863A>G p.D288G | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.11); catalogued as rs375273020; called by mutect2, varscan2
- GTDC1 | c.203T>A p.L68H | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53993805; called by muse, mutect2
- KIF1B | c.2356A>C p.K786Q (on ENST00000377086 / NM_001365952.1; = p.K740Q on NM_015074.3) | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.287); catalogued as COSV55808088; called by muse, mutect2, varscan2
- LAMA1 | c.7850C>T p.T2617M | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.607); catalogued as rs751200271, COSV67533423; called by mutect2, varscan2
- MAP2K4 | c.429del p.K143Nfs*9 | Frame Shift Del (DEL) | VAF 10/74 reads (14%) | catalogued as COSV62254718; called by mutect2, pindel, varscan2
- OR4A5 | c.804G>T p.M268I | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0.001); catalogued as COSV60522374; called by muse, mutect2, varscan2
- PABPC1 | c.1574A>G p.N525S | Missense Mutation (SNP) | VAF 14/123 reads (11%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as COSV59401157, COSV99073762; called by muse, mutect2, varscan2
- PMS1 | c.1438del p.E480Kfs*36 | Frame Shift Del (DEL) | VAF 14/116 reads (12%) | catalogued as COSV59716137; called by mutect2, varscan2
- PTPRK | c.2401A>G p.M801V (on ENST00000368215 / NM_001291984.2; = p.M802V on NM_002844.4) | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT tolerated (0.48); PolyPhen benign (0.011); catalogued as COSV63896531; called by muse, mutect2, varscan2
- RANBP2 | c.334G>T p.G112* | Nonsense Mutation (SNP) | VAF 100/775 reads (13%) | catalogued as COSV51700235; called by muse, mutect2, varscan2
- RBM33 | c.77C>G p.A26G | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55296815, COSV55299687; called by muse, mutect2
- SLC9C1 | c.338C>T p.P113L | Missense Mutation (SNP) | VAF 25/206 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59887834; called by muse, mutect2, varscan2
- ST6GALNAC5 | c.811T>C p.Y271H | Missense Mutation (SNP) | VAF 12/103 reads (12%) | PolyPhen probably damaging (0.999); catalogued as COSV59564815; called by muse, mutect2, varscan2
- TIMELESS | c.3205G>C p.V1069L | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV57511065; called by muse, mutect2, varscan2
- TRIM51 | c.766G>A p.E256K | Missense Mutation (SNP) | VAF 24/225 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.127); catalogued as rs1338462153, COSV55266148; called by muse, mutect2, varscan2
- XPO6 | c.724A>T p.S242C | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV58966079; called by muse, mutect2, varscan2
- ADGRF5 | c.875del p.V292Gfs*38 | Frame Shift Del (DEL) | VAF 12/85 reads (14%) | called by mutect2, pindel, varscan2
- CHD9 | c.6751del p.Y2251Ifs*13 | Frame Shift Del (DEL) | VAF 13/94 reads (14%) | called by mutect2, pindel, varscan2
- CSNK1A1L | c.488dup p.Y164Vfs*16 | Frame Shift Ins (INS) | VAF 38/254 reads (15%) | called by mutect2, pindel, varscan2
- KBTBD12 | c.936_938dup p.S313dup | In Frame Ins (INS) | VAF 19/150 reads (13%) | called by mutect2, pindel, varscan2
- OTOG | c.1488-1G>C p.X496_splice | Splice Site (SNP) | VAF 7/30 reads (23%) | called by muse, mutect2, varscan2
- ATP8A2 | c.2832C>T p.P944= | Silent (SNP) | VAF 11/55 reads (20%) | catalogued as COSV54949736; called by muse, mutect2, varscan2
- CIR1 | c.342C>T p.I114= | Silent (SNP) | VAF 15/134 reads (11%) | catalogued as COSV59595926; called by muse, mutect2, varscan2
- DNAH11 | c.13428C>T p.Y4476= | Silent (SNP) | VAF 8/39 reads (21%) | catalogued as rs530934832, COSV60953817; called by muse, mutect2, varscan2
- KDM5D | c.870G>A p.L290= | Silent (SNP) | VAF 21/69 reads (30%) | catalogued as COSV58736410; called by muse, mutect2, varscan2
- KIF21B | c.3024G>A p.E1008= | Silent (SNP) | VAF 8/76 reads (11%) | catalogued as rs766135570, COSV59757010; called by mutect2, varscan2
- MAP3K10 | c.162C>A p.G54= | Silent (SNP) | VAF 3/16 reads (19%) | called by mutect2, varscan2
- NUP205 | c.5712T>G p.L1904= | Silent (SNP) | VAF 20/169 reads (12%) | catalogued as COSV53657350; called by muse, mutect2, varscan2
- NYAP2 | c.489C>T p.A163= | Silent (SNP) | VAF 8/44 reads (18%) | catalogued as COSV56003972; called by muse, mutect2, varscan2
- OR4L1 | c.465C>T p.H155= | Silent (SNP) | VAF 14/96 reads (15%) | catalogued as rs771452167, COSV59849676; called by muse, mutect2, varscan2
- PGBD2 | c.702C>T p.N234= | Silent (SNP) | VAF 8/40 reads (20%) | catalogued as rs888823858, COSV61400107; called by muse, mutect2, varscan2
- STYK1 | c.945G>T p.L315= | Silent (SNP) | VAF 13/117 reads (11%) | catalogued as COSV50013061; called by muse, mutect2, varscan2
- TM4SF5 | c.525C>T p.I175= | Silent (SNP) | VAF 18/68 reads (26%) | catalogued as COSV54496484; called by muse, mutect2, varscan2
- USH2A | c.759T>C p.T253= | Silent (SNP) | VAF 18/106 reads (17%) | catalogued as COSV56363197, COSV56422403; called by muse, mutect2
- BACE2 | c.312+15286A>G | Intron (SNP) | VAF 5/60 reads (8%) | called by muse, mutect2
- ELK4 | c.1080+122G>A | Intron (SNP) | VAF 16/96 reads (17%) | catalogued as COSV56984749; called by muse, mutect2, varscan2
- LINC01548 | n.374G>A | RNA (SNP) | VAF 7/50 reads (14%) | catalogued as rs551756589; called by mutect2, varscan2
- PLPP4 | c.57-218G>A | Intron (SNP) | VAF 14/99 reads (14%) | called by muse, mutect2, varscan2
- PRDM2 | c.*58G>A | 3'UTR (SNP) | VAF 17/109 reads (16%) | catalogued as COSV99341432; called by muse, mutect2, varscan2
- RBM15B | c.*2654G>T | 3'UTR (SNP) | VAF 13/102 reads (13%) | catalogued as COSV100082086; called by muse, mutect2, varscan2
- SPX | c.*11G>T | 3'UTR (SNP) | VAF 28/210 reads (13%) | catalogued as COSV99679678, COSV99680231; called by muse, mutect2, varscan2
